Surgical pathology report (de-identified scan), TCGA case TCGA-DC-6157, project TCGA-READ (Rectum Adenocarcinoma), tissue source site MSKCC, specimen TCGA-DC-6157-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:
Rectosigmoid cancer.

Specimens Submitted:

- 1: SP: Sigmoid and upper rectum ([REDACTED])
- 2: SP: Additional proximal sigmoid ([REDACTED])
- 3: SP: Distal anastomotic ring ([REDACTED])
- 4: SP: Proximal anastomotic ring ([REDACTED])

DIAGNOSIS:

- 1. LARGE BOWEL, SIGMOID, UPPER RECTUM; RESECTION:
- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR BUDDING IS IDENTIFIED AT THE BASE OF THE TUMOR.
- TUMOR LOCATION: RECTOSIGMOID.
- TUMOR SIZE: LENGTH IS 4.0 CM, WIDTH IS 2.8 CM, MAXIMAL THICKNESS IS 0.8 CM.
- GROSS CONFIGURATION: PLAQUE-LIKE.
- TUMOR INVASION: INVASION INTO MUSCULARIS PROPRIA.
- GROSS TUMOR PERFORATION: NOT IDENTIFIED.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR; TUMOR IS 5.8 CM FROM THE DISTAL MARGIN.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC [REDACTED]): pT2.
- LYMPH NODES: NUMBER WITH METASTASES: 0, NUMBER EXAMINED: 21.
- THE PATHOLOGIC STAGE IS (AJCC [REDACTED]): pN0.
- 2. COLON, SIGMOID, ADDITIONAL PROXIMAL; RESECTION:
- SEGMENT OF BENIGN COLON WITH ACUTE SEROSITIS.
- MARGINS FREE OF TUMOR.
- 3. COLON, DISTAL ANASTOMOTIC RING; EXCISION:
- BENIGN COLONIC TISSUE.
- 4. COLON, PROXIMAL ANASTOMOTIC RING; EXCISION:
- BENIGN COLONIC TISSUE.

** Continued on next page **

[page 2 of 4]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh and is labeled "sigmoid and upper rectum". It consists of a rectosigmoid colon that measures 35.5 x 7.2cm in circumference at the distal margin. The serosal surface is pink tan and smooth. The radial resection margin is inked black and the specimen is opened to reveal a pink brown papillary tumor measuring 4.0 cm in length by 2.8 cm x 0.8 cm, located 5.8 cm from the nearest (distal) margin. The tumor is sectioned to reveal extension to a depth of 0.6 cm involving the underlying muscularis, and 0.3 cm from the nearest radial margin. is taken. The specimen is submitted for lymph node dissection and all identified lymph nodes are submitted. Representative sections are submitted.

Summary of sections:

P -- proximal margin
D -- distal margin
RM -- radial margin
T -- tumor
RS- representative section
LN -- lymph nodes

2). The specimen is received fresh labeled "additional proximal sigmoid", and it consists of an unoriented portion of bowel measuring 3.1 cm in length x 2.2 cm in diameter. There is an undesignated one opened end and an opposing undesignated stapled margin. The specimen is opened to reveal grossly unremarkable pink-tan mucosal folds. No discrete lesions or gross abnormalities are identified. Representative sections are submitted.

Summary:

OM-- open end margin
SM-- stapled margin
RS - representative sections

3). The specimen is received in formalin, labeled "distal anastomotic ring" and consists of a ring of pink tan soft tissue measuring 1.8 x 1.8 x 0.7 cm. Multiple sutures and staples are attached. The mucosal surface is pink tan

** Continued on next page **

[page 3 of 4]
----- Page 3 of 4
and focally hemorrhagic. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
Undesignated

4). The specimen is received in formalin, labeled "proximal anastomotic ring" and consists of a silver metal anastomotic pin measuring 7.5 X 2.8 X 1.5 cm. At the center of the pin, a plastic piece is noted. A ring of pink tan soft tissue is attached measuring 1.8 x 1.8 x 0.7 cm. The mucosal surface is pink tan and focally hemorrhagic and the serosal surface is pink tan and smooth. Several sutures and staples are noted. The sutures and staples are removed and the soft tissue is entirely submitted.

Summary of sections:
U--undesignated

Summary of Sections:

Part 1: SP: Sigmoid and upper rectum

Block	Sect.	Site	PCs
2		d	2
6		ln	15
1		p	1
1		rm	1
1		rs	1
3		t	3

Part 2: SP: Additional proximal sigmoid

Block	Sect.	Site	PCs
1		om	1
1		rs	1
1		sm	1

Part 3: SP: Distal anastomotic ring

Block	Sect.	Site	PCs
2		u	2

Part 4: SP: Proximal anastomotic ring

Block	Sect.	Site	PCs
2		u	2

** Continued on next page **

[page 4 of 4]
[REDACTED]

** End of Report **

Source: NCI Genomic Data Commons file 80640440-598c-4586-9535-aa280e766883 (TCGA-DC-6157.7445AADB-AA7E-4968-9A0E-D77A0AA25294.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).